Somatic mutation profile of tumor specimen TCGA-DD-AADE-01A (aliquot TCGA-DD-AADE-01A-11D-A40R-10) from TCGA case TCGA-DD-AADE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 50.6 years (18,482 days).
Specimen TCGA-DD-AADE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03bf85ba-a68a-4534-a7f7-6c13a3413ec5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADE-10A (Blood Derived Normal), aliquot TCGA-DD-AADE-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71ae1f08-6ebc-41c5-a20e-66fa7fb93a79

The open-access MAF lists 126 somatic variants for this specimen: 93 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 31, Frame Shift Del 6, Nonsense Mutation 6, In Frame Del 3, Splice Site 2, Intron 2, Frame Shift Ins 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 38/126 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, varscan2
- CTNNB1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ACBD4 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV100416363; called by muse, mutect2, varscan2
- ATP10B | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as rs374261198, COSV100515633; called by muse, mutect2, varscan2
- C20orf194 | c.1364T>C p.M455T | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99331709; called by muse, varscan2
- CACNA1G | c.2422A>T p.N808Y | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100662726; called by muse, mutect2, varscan2
- CCDC62 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99457853; called by muse, mutect2, varscan2
- CDK11B | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as COSV100478392; called by muse, mutect2
- CDK14 | c.754A>G p.I252V (on ENST00000380050 / NM_001287135.2; = p.I234V on NM_012395.3) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV99727429; called by muse, mutect2, varscan2
- CFP | c.809C>G p.P270R | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV99901725; called by muse, mutect2, varscan2
- CLN3 | c.606C>T p.S202= (on ENST00000360019 / NM_001286104.2; = p.S226= on NM_000086.2) | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100343496, COSV100343779; called by muse, mutect2, varscan2
- CUL4A | c.1562T>C p.I521T (on ENST00000375440 / NM_001008895.4; = p.I421T on NM_003589.3) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV100417600; called by muse, mutect2, varscan2
- DAAM2 | c.289A>G p.S97G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99227520; called by muse, mutect2, varscan2
- DCUN1D5 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs1565285586, COSV99499287; called by muse, mutect2, varscan2
- DHX30 | c.1183G>A p.D395N (on ENST00000445061 / NM_138615.3; = p.D356N on NM_014966.3) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV99276508; called by muse, mutect2, varscan2
- DLG1 | c.398A>C p.E133A | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as COSV100016183; called by muse, mutect2, varscan2
- DOCK10 | c.3385T>C p.S1129P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV99292181; called by muse, mutect2, varscan2
- EPB41L5 | c.734A>T p.Y245F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99759336; called by muse, mutect2, varscan2
- EVC | c.2798C>T p.T933I | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV99381645, COSV99382753; called by muse, mutect2, varscan2
- FER1L6 | c.4471G>T p.G1491* | Nonsense Mutation (SNP) | VAF 35/266 reads (13%) | catalogued as COSV101206246; called by muse, mutect2, varscan2
- FLG | c.6482C>G p.S2161C | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100912401, COSV64244120; called by muse, mutect2, varscan2
- GABRA2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62913387; called by muse, mutect2, varscan2
- GLRB | c.1484T>C p.I495T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100030234; called by muse, mutect2, varscan2
- GMIP | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); catalogued as COSV99179677; called by muse, mutect2, varscan2
- GPX2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV100767506, COSV63036658; called by muse, mutect2, varscan2
- GSDME | c.1491A>T p.*497Cext*4 | Nonstop Mutation (SNP) | VAF 53/133 reads (40%) | catalogued as COSV99757960; called by muse, mutect2, varscan2
- HABP2 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1425448008, COSV100668123; called by muse, mutect2, varscan2
- HABP2 | c.465G>T p.R155S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.16); catalogued as COSV100668124; called by muse, mutect2, varscan2
- HSP90AB1 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100807242, COSV62333189; called by muse, mutect2, varscan2
- KCTD3 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99379879; called by muse, mutect2, varscan2
- MAP3K12 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99913685; called by mutect2, varscan2
- MARS1 | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100007764; called by muse, mutect2, varscan2
- MARVELD2 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100348000; called by muse, mutect2, varscan2
- MEST | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV99784452; called by muse, mutect2, varscan2
- METTL6 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101085115; called by muse, mutect2, varscan2
- MMP9 | c.1709T>C p.V570A | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100812482; called by muse, mutect2, varscan2
- MOCOS | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99734007; called by muse, mutect2, varscan2
- MOCOS | c.2409G>A p.Q803= | Splice Region (SNP) | VAF 40/100 reads (40%) | catalogued as COSV99734011; called by muse, mutect2, varscan2
- MPG | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV99550117; called by muse, mutect2, varscan2
- MVD | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99880178; called by muse, mutect2, varscan2
- MYBL1 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 89/584 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV101576620; called by muse, mutect2, varscan2
- NEUROG1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100130877, COSV100130878; called by muse, mutect2
- NLRP4 | c.2192T>C p.V731A | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56717108; called by muse, mutect2, varscan2
- NR0B2 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54259447, COSV99575111; called by muse, mutect2, varscan2
- NTRK1 | c.1973T>C p.V658A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV100693880; called by muse, mutect2, varscan2
- OCA2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs372901106, COSV62338601; called by muse, mutect2
- PARD6B | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100860075; called by muse, mutect2, varscan2
- PCDH8 | c.214T>A p.S72T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100132131; called by muse, mutect2, varscan2
- PIGN | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 135/451 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV100716285; called by muse, mutect2, varscan2
- POLR1A | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs185579866, COSV99808616; called by muse, mutect2, varscan2
- POM121L12 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV68692463; called by muse, mutect2, varscan2
- PPP2R3B | c.1188G>T p.W396C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101180845; called by muse, mutect2, varscan2
- PRKCSH | c.1541A>C p.E514A | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV99372044; called by muse, mutect2, varscan2
- PROKR1 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs746208336, COSV100375804; called by muse, mutect2, varscan2
- PTGS2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV66568705, COSV66568911; called by muse, mutect2, varscan2
- PTPRT | c.2661C>A p.Y887* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV61966418, COSV61977890; called by muse, mutect2, varscan2
- RAB15 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99962236; called by muse, mutect2, varscan2
- RBM27 | c.850+1G>A p.X284_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as COSV99506759; called by muse, mutect2, varscan2
- RCOR1 | c.1269T>G p.F423L | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99217864; called by muse, mutect2, varscan2
- RNF213 | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.05); catalogued as COSV100174113; called by muse, mutect2, varscan2
- RNF213 | c.261+2T>A p.X87_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as rs74367834, COSV100174116; called by muse, mutect2, varscan2
- SBNO1 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99929886; called by muse, mutect2, varscan2
- SCAPER | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57733631; called by muse, mutect2, varscan2
- SCN4A | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs764029151, COSV71129559; called by muse, mutect2, varscan2
- SETD3 | c.1688C>G p.T563S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.024); catalogued as COSV100075595; called by muse, mutect2, varscan2
- SHPRH | c.2672A>G p.H891R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV99262848; called by muse, mutect2, varscan2
- SLC19A3 | c.1378A>G p.I460V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV99296184; called by muse, mutect2, varscan2
- SLC6A14 | c.1907G>A p.S636N | Missense Mutation (SNP) | VAF 187/273 reads (68%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100902634; called by muse, mutect2, varscan2
- SLC7A6OS | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV99546937; called by muse, mutect2, varscan2
- SORCS3 | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100865725; called by muse, mutect2, varscan2
- TAFA1 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101524566; called by muse, mutect2, varscan2
- TRHDE | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99673073; called by muse, mutect2, varscan2
- TUT1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99545681; called by muse, mutect2, varscan2
- USP9X | c.5566G>T p.E1856* | Nonsense Mutation (SNP) | VAF 127/170 reads (75%) | catalogued as COSV100200275; called by muse, mutect2, varscan2
- VCAM1 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.03); catalogued as rs770478132, COSV99659021; called by muse, mutect2, varscan2
- VN1R1 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100320795; called by muse, mutect2, varscan2
- VSTM2A | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100173475, COSV56495692; called by muse, mutect2, varscan2
- ZCCHC12 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV100038714; called by muse, mutect2
- AVPR1B | c.839_865del p.V280_L288del | In Frame Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- CDK11A | c.1100G>T p.R367L (on ENST00000378633 / NM_001313896.2; = p.R364L on NM_024011.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); called by muse, mutect2
- DVL1 | c.1099_1101del p.T367del | In Frame Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- IGKV2D-24 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IL6ST | c.646_648del p.P216del | In Frame Del (DEL) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- MDN1 | c.8319del p.V2774Ffs*22 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- MRPL45 | c.604A>T p.M202L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC2 | c.3371A>G p.Y1124C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- NPHP3 | c.3949del p.T1317Qfs*19 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | called by mutect2, pindel, varscan2
- NR1H4 | c.1042_1051del p.E348Ifs*26 (on ENST00000551379 / NM_001206993.2; = p.E334Ifs*26 on NM_005123.4) | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- NR2C1 | c.156_160del p.T53Kfs*34 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- OR5K4 | c.652_656del p.Y218Lfs*17 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- RAB8A | c.318dup p.E107* | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- SECISBP2L | c.3028_3029del p.E1010Sfs*5 (on ENST00000559471 / NM_001193489.2; = p.E965Sfs*5 on NM_014701.4) | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- SYNM | c.3708dup p.Q1237Sfs*12 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- ANPEP | c.1680C>G p.T560= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV100263629; called by muse, mutect2, varscan2
- ASL | c.786C>G p.L262= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV59190258; called by muse, mutect2, varscan2
- C2orf15 | c.69T>C p.D23= | Silent (SNP) | VAF 80/230 reads (35%) | catalogued as COSV100209111; called by muse, mutect2, varscan2
- CAMKK2 | c.534C>T p.V178= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs377203622, COSV100243274; called by muse, mutect2, varscan2
- CEACAM20 | c.501G>A p.L167= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100387062; called by muse, mutect2, varscan2
- CLEC12B | c.6T>C p.S2= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100139155; called by muse, mutect2
- COL11A2 | c.720G>A p.Q240= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100554639; called by muse, mutect2, varscan2
- CSPG4 | c.2815C>A p.R939= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1362202520, COSV100414279; called by muse, mutect2, varscan2
- DVL2 | c.153G>T p.A51= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as rs987969510, COSV99138982; called by muse, mutect2, varscan2
- EBF3 | c.720C>T p.H240= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs368078346; called by muse, mutect2, varscan2
- ERMN | c.474A>G p.E158= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs749945115, COSV101263081; called by muse, mutect2, varscan2
- FASTKD5 | c.1170T>A p.V390= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as COSV53909519, COSV99418702; called by muse, mutect2, varscan2
- FLG2 | c.3687A>T p.G1229= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV101166307; called by muse, mutect2, varscan2
- GRIN1 | c.1839C>A p.V613= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100160829; called by muse, varscan2
- HEATR5B | c.2334C>T p.V778= | Silent (SNP) | VAF 141/463 reads (30%) | catalogued as COSV51858399, COSV99250409; called by muse, mutect2, varscan2
- INTS2 | c.831T>C p.L277= | Silent (SNP) | VAF 146/284 reads (51%) | catalogued as COSV99249018; called by muse, mutect2, varscan2
- KANK2 | c.1839G>A p.E613= (on ENST00000586659 / NM_001379562.1; = p.E621= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100763468; called by muse, mutect2, varscan2
- MAP3K21 | c.2793C>T p.V931= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV100786122; called by muse, mutect2, varscan2
- NFRKB | c.1770G>A p.L590= (on ENST00000446488 / NM_001143835.2; = p.L615= on NM_006165.3) | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs767896548, COSV100452137; called by muse, mutect2, varscan2
- NMUR1 | c.972A>G p.S324= | Silent (SNP) | VAF 65/190 reads (34%) | catalogued as COSV100532185; called by muse, mutect2, varscan2
- NR1H2 | c.1356G>C p.L452= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs762279456, COSV99516600; called by muse, mutect2, varscan2
- NSD2 | c.1908C>T p.P636= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100374060; called by muse, mutect2, varscan2
- NXPH1 | c.240A>G p.E80= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV101339838; called by muse, mutect2
- PPP4R3B | c.333G>A p.Q111= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99702852; called by muse, mutect2, varscan2
- PSMC4 | c.48A>T p.P16= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99338469; called by muse, varscan2
- SLC25A26 | c.420G>A p.L140= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV100377390; called by muse, mutect2, varscan2
- SLC9A2 | c.1338G>T p.V446= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV99296977; called by muse, mutect2, varscan2
- SPATA25 | c.264A>C p.R88= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs752671899, COSV99510200; called by muse, mutect2, varscan2
- TMPRSS3 | c.498G>A p.R166= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV99368822; called by muse, mutect2, varscan2
- TNXB | c.5808A>G p.S1936= (on ENST00000647633; = p.S1689= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs1365261130, COSV100926765; called by muse, mutect2, varscan2
- ZNF140 | c.1287T>C p.A429= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100166891; called by muse, mutect2, varscan2
- MAX | c.295+11G>T | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as rs759033476, COSV99408688; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1878T>A | Intron (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100002770; called by muse, mutect2, varscan2
